TCGA case TCGA-IW-A3M6 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3ea1cbd8-f74a-4b14-aa49-23d5a47716ba

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Alive.

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 59.3 years (21,674 days); Year of diagnosis: 2011; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Uterus; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Necrosis present: Yes; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 9; Tumor length measurement: 13.5; Tumor width measurement: 9.5.
2. Intraductal carcinoma, noninfiltrating, NOS: ICD-O-3 morphology code: 8500/2; Tissue or organ of origin: Breast, NOS; Classification of tumor: Prior primary; AJCC pathologic T: Tis (DCIS); AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage 0is.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 1.
- Days to follow up: 688 days (1.9 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 45.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IW-A3M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-IW-A3M6-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-IW-A3M6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IW-A3M6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Discontinuous lesions count: 1; Locoregional recurrence indicator: No; Metastatic disease confirmed: No; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 9.0.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 24; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 24; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Ductal Carcinoma In-situ.
- Other malignancy form, Drug treatment, Administered drug 1: Pharmaceutical therapy drug name: Tamoxifen.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of acceptable prior treatment related to a prior/other malignancy: Patient had a prior DCIS in the breast. Patient received local radiation but no systemic therapy. Sarcoma is a uterine leiomyosarcoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 688 days; disease-specific survival: no event (censored), 688 days; disease-free interval: no event (censored), 688 days; progression-free interval: no event (censored), 688 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IW-A3M6-01A-11D-A21P-01): tumor purity 0.75, ploidy 1.72, whole-genome doublings 0.
